EXCEPTIONAL_RESPONDERS case ER-B0AT — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7f5ca024-fd98-4cb9-a076-32b47bcbb14c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1964; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,077 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,707 days (4.7 years); Days to best overall response: 368 days (1.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine + Cisplatin; Days to treatment start: 51 days; Days to treatment end: 156 days.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 51 days.

Follow-up (1 entry)
- Days to follow up: 1,707 days (4.7 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,707 days (4.7 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0AT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0AT-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 55; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
